Gene-level copy-number profile of tumor specimen TCGA-Q1-A5R3-01A from TCGA case TCGA-Q1-A5R3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G2; Age at diagnosis: 56.3 years (20,574 days).
Specimen TCGA-Q1-A5R3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.8e5da6ef-001a-4766-929e-c2d191616f06.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Q1-A5R3-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e59bb453-d915-4123-baf7-3396f714f1fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,135; copy number 2: 39,531; copy number 3: 11,948; copy number 4: 2,328; copy number 5: 1,167; copy number 6: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Q1-A5R3-01A-11D-A28A-01): tumor purity 0.72, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,877 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,811,768–198,222,513, 1,167 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
